Somatic mutation profile of tumor specimen TCGA-ZB-A96I-01A (aliquot TCGA-ZB-A96I-01A-11D-A428-09) from TCGA case TCGA-ZB-A96I, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 71.8 years (26,208 days).
Specimen TCGA-ZB-A96I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e7b8f3b-68cc-4e6f-b166-0c72f7795559.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96I-10A (Blood Derived Normal), aliquot TCGA-ZB-A96I-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/032b683e-e417-404b-97d4-f9207aab15c0

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LUZP1 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs533244242; called by muse, mutect2, varscan2
- NSD1 | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs775181583; called by muse, mutect2, varscan2
- SH3YL1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV62156267; called by muse, mutect2, varscan2
- SIK3 | c.877G>C p.V293L (on ENST00000445177 / NM_001366686.2; = p.V299L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs769590697; called by muse, mutect2, varscan2
- WIF1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1488501517; called by muse, mutect2, varscan2
- ZNF431 | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs537787342, COSV100219080; called by muse, mutect2, varscan2
- ZNF676 | c.1056G>C p.W352C (on ENST00000650058; = p.W320C on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV101236216, COSV101236247; called by muse, mutect2, varscan2
- BUB1 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CALD1 | c.1712A>G p.K571R (on ENST00000361675 / NM_033138.4; = p.K316R on NM_004342.7) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.624); called by muse, mutect2
- DHX30 | c.1270C>T p.R424* (on ENST00000445061 / NM_138615.3; = p.R385* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- EXT1 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- MAPK8IP3 | c.3506T>C p.I1169T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MGA | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- NISCH | c.3457-1G>T p.X1153_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- NRG1 | c.1813T>G p.F605V (on ENST00000405005 / NM_013964.5; = p.F610V on NM_013956.5) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- PCSK6 | c.657T>C p.Y219= | Splice Region (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1561del p.I521Yfs*11 (on ENST00000521381 / NM_181523.3; = p.I251Yfs*11 on NM_181504.4) | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | called by mutect2, pindel, varscan2
- PTPRE | c.1318A>T p.K440* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- SLC22A9 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- SPTY2D1 | c.1906del p.Y636Mfs*21 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- SRRM2 | c.5017A>G p.R1673G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CRAT | c.1701G>A p.G567= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- HAO2 | c.882T>C p.A294= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- NEUROD4 | c.705G>A p.S235= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs528788272, COSV99670269; called by muse, mutect2, varscan2
- ZNF827 | c.1944A>C p.S648= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- DMAC2 | c.*902del | 3'UTR (DEL) | VAF 38/122 reads (31%) | called by mutect2, pindel, varscan2
